Somatic mutation profile of tumor specimen 0DMKN9 from CCDI case PBCALC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.0 years (1,840 days).
Specimen 0DMKN9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7542e1d3-7807-411b-8923-331eef494651.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKKK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/393fce23-0dd9-4a80-9567-cf5d2cfb4c9c

The open-access MAF lists 40 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Intron 8, Silent 7, Nonsense Mutation 3, 3'UTR 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 627/1049 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906589, CM091421, COSV55115990, COSV55115998; ClinVar: likely pathogenic / other; called by muse, mutect2, varscan2
- H3C2 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 282/636 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52517710, COSV52518111; called by muse, mutect2, varscan2
- ATM | c.5044G>T p.D1682Y | Missense Mutation (SNP) | VAF 158/368 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM0910509, COSV53728454, COSV53735978; called by muse, mutect2, varscan2
- FAT4 | c.6035C>G p.S2012C | Missense Mutation (SNP) | VAF 114/562 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100628823; called by mutect2, varscan2
- KCNV2 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 202/454 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs201520619; called by muse, mutect2, varscan2
- OR51M1 | c.835C>A p.H279N | Missense Mutation (SNP) | VAF 234/551 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV60785396, COSV99061922; called by muse, mutect2, varscan2
- ADGRE5 | c.2242C>A p.L748M (on ENST00000242786 / NM_078481.4; = p.L655M on NM_001784.5) | Missense Mutation (SNP) | VAF 299/674 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATM | c.4436G>T p.R1479M | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- C6 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 265/646 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRACD | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 99/658 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- G2E3 | c.839G>T p.W280L | Missense Mutation (SNP) | VAF 131/327 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRAMD1C | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 115/358 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPG2 | c.9853G>T p.G3285W | Missense Mutation (SNP) | VAF 349/693 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMS22L | c.3103C>A p.L1035I | Missense Mutation (SNP) | VAF 259/598 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- MTOR | c.7522C>A p.L2508I | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC4 | c.15089G>T p.R5030M (on ENST00000463781 / NM_018406.7; = p.R794M on NM_004532.6) | Missense Mutation (SNP) | VAF 377/896 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- NEB | c.17224C>T p.R5742* | Nonsense Mutation (SNP) | VAF 164/583 reads (28%) | called by muse, mutect2, varscan2
- PIK3R1 | c.1713_1718del p.I571_L573delinsM (on ENST00000521381 / NM_181523.3; = p.I301_L303delinsM on NM_181504.4) | In Frame Del (DEL) | VAF 153/497 reads (31%) | called by mutect2, pindel, varscan2
- POLDIP3 | c.150C>A p.F50L | Missense Mutation (SNP) | VAF 325/799 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- RYR1 | c.5686G>T p.E1896* | Nonsense Mutation (SNP) | VAF 317/665 reads (48%) | called by muse, mutect2, varscan2
- WIPF3 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 182/366 reads (50%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.027); called by mutect2, varscan2
- ZNF668 | c.1563C>A p.C521* | Nonsense Mutation (SNP) | VAF 135/336 reads (40%) | called by muse, mutect2, varscan2
- ZNF74 | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 214/516 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DAAM2 | c.687G>T p.V229= | Silent (SNP) | VAF 390/890 reads (44%) | called by muse, mutect2, varscan2
- GRIK3 | c.123C>A p.I41= | Silent (SNP) | VAF 142/338 reads (42%) | catalogued as COSV66137344; called by muse, mutect2, varscan2
- KRT35 | c.1149G>A p.L383= | Silent (SNP) | VAF 433/1056 reads (41%) | called by muse, mutect2, varscan2
- MPPED1 | c.162C>A p.P54= | Silent (SNP) | VAF 243/578 reads (42%) | called by muse, mutect2, varscan2
- OR1L4 | c.669C>T p.I223= | Silent (SNP) | VAF 156/1332 reads (12%) | catalogued as rs140014211, COSV52341184; called by muse, varscan2
- PKP3 | c.1239G>T p.R413= | Silent (SNP) | VAF 247/568 reads (43%) | catalogued as COSV58989420; called by muse, mutect2, varscan2
- TRPV5 | c.1530C>A p.I510= | Silent (SNP) | VAF 276/589 reads (47%) | called by muse, mutect2, varscan2
- ABLIM3 | c.1858-32C>A | Intron (SNP) | VAF 83/193 reads (43%) | called by muse, mutect2, varscan2
- BAIAP2L1 | c.*51G>T | 3'UTR (SNP) | VAF 132/330 reads (40%) | called by muse, mutect2
- IL5 | c.144+76G>A | Intron (SNP) | VAF 96/215 reads (45%) | called by muse, mutect2, varscan2
- KATNB1 | c.1567-34C>G | Intron (SNP) | VAF 100/255 reads (39%) | catalogued as rs1320844846, COSV65549157; called by muse, mutect2, varscan2
- KIAA0319L | c.1657-89G>T | Intron (SNP) | VAF 91/201 reads (45%) | called by muse, mutect2, varscan2
- MAP11 | c.846-14C>A | Intron (SNP) | VAF 229/568 reads (40%) | called by muse, mutect2, varscan2
- MYOCD | c.2245+47G>T | Intron (SNP) | VAF 137/285 reads (48%) | called by muse, mutect2, varscan2
- RPS7 | c.*27T>C | 3'UTR (SNP) | VAF 17/346 reads (5%) | catalogued as rs1238573533; called by muse, mutect2
- TSC22D1 | c.2964+36G>T | Intron (SNP) | VAF 130/330 reads (39%) | called by muse, mutect2, varscan2
- UBE2B | c.331-99G>A | Intron (SNP) | VAF 30/82 reads (37%) | called by mutect2, varscan2
